Somatic mutation profile of cancer-model specimen HCM-BROD-0196-C71-85A (Adherent Cell Line, passage 10; aliquot HCM-BROD-0196-C71-85A-01D-A786-36), derived from the primary tumor of HCMI case HCM-BROD-0196-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.9 years (21,887 days).
Specimen HCM-BROD-0196-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 590ae688-4159-4665-aa94-6a9f19b8c252.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0196-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0196-C71-10A-01D-A786-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f46a326-7f62-463a-8130-bfb253cd8d45

The open-access MAF lists 102 somatic variants for this specimen: 68 protein-altering or splice-affecting, 17 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 17, Intron 8, RNA 3, 3'UTR 2, Nonsense Mutation 2, Splice Site 2, 5'UTR 2, 5'Flank 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 64/529 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AK9 | c.4739G>T p.W1580L | Missense Mutation (SNP) | VAF 13/206 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs938709559; called by muse, mutect2
- AMDHD2 | c.646C>G p.L216V | Missense Mutation (SNP) | VAF 69/307 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV99565843; called by muse, mutect2, varscan2
- CDH7 | c.1019G>A p.R340Q | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.765); catalogued as rs1420186009, COSV59886253; called by muse, varscan2
- CTSC | c.523G>T p.V175L | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as COSV57059415; called by muse, mutect2
- F9 | c.814G>A p.G272S | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.103); catalogued as COSV99496177; called by muse, mutect2
- FKBP9 | c.1702G>A p.D568N | Missense Mutation (SNP) | VAF 40/216 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs762749018, COSV54227811, COSV54229232; called by muse, mutect2, varscan2
- GPSM2 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 104/217 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs757559568, COSV51443037, COSV51443915; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGHE | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 192/366 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.377); catalogued as rs377424997; called by muse, mutect2, varscan2
- IL1R1 | c.1628G>A p.R543Q | Missense Mutation (SNP) | VAF 85/195 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0.024); catalogued as rs749524190, COSV52105792; called by muse, mutect2, varscan2
- ITPR1 | c.282C>T p.H94= | Splice Region (SNP) | VAF 19/145 reads (13%) | catalogued as rs749104116, COSV56975983; called by muse, mutect2, varscan2
- KRIT1 | c.413T>C p.I138T | Missense Mutation (SNP) | VAF 116/402 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as rs1172939308, CS108376; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRFN5 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 87/208 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1358755376, COSV53254064; called by muse, mutect2, varscan2
- MMP7 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.348); catalogued as rs773617283, COSV52771873; called by muse, mutect2, varscan2
- NDEL1 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765053880, COSV55326803; called by muse, mutect2, varscan2
- OR5F1 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 50/96 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs190524347, COSV53546231; called by muse, mutect2, varscan2
- PCLO | c.11395C>T p.R3799* | Nonsense Mutation (SNP) | VAF 105/371 reads (28%) | catalogued as COSV61656825; called by muse, mutect2, varscan2
- PPAT | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51706784; called by muse, mutect2, varscan2
- PPIC | c.360G>C p.E120D | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV100120600, COSV60574579; called by muse, mutect2, varscan2
- PSG6 | c.857A>T p.K286M | Missense Mutation (SNP) | VAF 69/616 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV51833522; called by muse, mutect2, varscan2
- PTEN | c.492+1G>A p.X164_splice | Splice Site (SNP) | VAF 68/68 reads (100%) | catalogued as CD020869, COSV64293587, COSV64301805, COSV64306784; called by muse, mutect2, varscan2
- SCN4A | c.904G>A p.G302S | Missense Mutation (SNP) | VAF 179/412 reads (43%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); catalogued as rs756852107, COSV101438326; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLITRK5 | c.911G>C p.G304A | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs1455000324; called by muse, mutect2
- SMARCA4 | c.3056C>T p.T1019I | Missense Mutation (SNP) | VAF 26/669 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV60803024; called by muse, mutect2
- SORCS3 | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 111/112 reads (99%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs979252992; called by muse, mutect2, varscan2
- SPATA17 | c.683G>T p.R228L | Missense Mutation (SNP) | VAF 13/199 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs761102893; called by muse, mutect2
- SPTA1 | c.3767C>A p.A1256D | Missense Mutation (SNP) | VAF 87/305 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.665); catalogued as COSV63760259; called by muse, mutect2, varscan2
- TEKT2 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 266/521 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375676685, COSV99255507; called by muse, mutect2, varscan2
- TTN | c.5942G>T p.R1981M (on ENST00000591111; = p.R1935M on NM_003319.4) | Missense Mutation (SNP) | VAF 35/490 reads (7%) | PolyPhen possibly damaging (0.855); catalogued as COSV100608881; called by muse, mutect2
- UNC80 | c.5603T>C p.V1868A | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.954); catalogued as rs1360788571; called by muse, mutect2
- WDR64 | c.3139G>A p.G1047R | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.362); catalogued as rs899070310; called by muse, mutect2, varscan2
- XIRP2 | c.9385C>T p.R3129C (on ENST00000628543; = p.R3304C on NM_152381.6) | Missense Mutation (SNP) | VAF 106/209 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs374718160, COSV99748747; called by muse, mutect2, varscan2
- ZNF808 | c.319G>C p.E107Q | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV63119519; called by muse, mutect2, varscan2
- ABCA9 | c.4640+1G>T p.X1547_splice | Splice Site (SNP) | VAF 85/155 reads (55%) | called by muse, mutect2, varscan2
- ASMT | c.487G>C p.V163L | Missense Mutation (SNP) | VAF 374/792 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- CNTNAP2 | c.2216C>A p.P739H | Missense Mutation (SNP) | VAF 156/754 reads (21%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- CSMD3 | c.5311G>A p.G1771S (on ENST00000297405 / NM_001363185.1; = p.G1667S on NM_052900.3) | Missense Mutation (SNP) | VAF 57/212 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSNK1E | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 78/166 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCC | c.504G>A p.M168I | Missense Mutation (SNP) | VAF 14/411 reads (3%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2
- EPAS1 | c.1155G>T p.K385N | Missense Mutation (SNP) | VAF 26/412 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.328); called by muse, mutect2
- EPHX4 | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 73/73 reads (100%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- ESR1 | c.1144G>T p.A382S | Missense Mutation (SNP) | VAF 12/364 reads (3%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.561); called by muse, mutect2
- ETS2 | c.742A>C p.S248R | Missense Mutation (SNP) | VAF 212/451 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- GYPA | c.144C>A p.H48Q | Missense Mutation (SNP) | VAF 125/253 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KIF26B | c.529T>A p.W177R | Missense Mutation (SNP) | VAF 66/184 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- KLF16 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT tolerated (0.54); PolyPhen benign (0.385); called by muse, mutect2, varscan2
- LGR6 | c.2507A>G p.D836G (on ENST00000367278 / NM_001017403.1; = p.D784G on NM_021636.3) | Missense Mutation (SNP) | VAF 65/133 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- LY9 | c.1208C>A p.A403D | Missense Mutation (SNP) | VAF 36/496 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- MATR3 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 89/193 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MINDY3 | c.418G>C p.A140P | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- MRPS23 | c.154C>T p.R52* | Nonsense Mutation (SNP) | VAF 86/208 reads (41%) | called by muse, mutect2, varscan2
- NPY5R | c.843C>A p.F281L | Missense Mutation (SNP) | VAF 76/132 reads (58%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- OGG1 | c.950G>A p.G317D | Missense Mutation (SNP) | VAF 12/286 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.193); called by muse, mutect2
- PDGFD | c.947G>T p.C316F | Missense Mutation (SNP) | VAF 16/337 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- PDZD8 | c.1611A>G p.I537M | Missense Mutation (SNP) | VAF 97/97 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- PMF1 | c.460A>G p.K154E | Missense Mutation (SNP) | VAF 14/363 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0.012); called by muse, mutect2
- PRAMEF17 | c.821T>A p.I274K | Missense Mutation (SNP) | VAF 131/433 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- PRRT2 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 174/330 reads (53%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PSMB8 | c.713G>T p.R238I (on ENST00000374882 / NM_148919.4; = p.R234I on NM_004159.5) | Missense Mutation (SNP) | VAF 12/343 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PTPN3 | c.2342T>A p.I781N | Missense Mutation (SNP) | VAF 62/390 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RPS21 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 52/97 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- SEMA6A | c.2596C>T p.H866Y | Missense Mutation (SNP) | VAF 33/297 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- SLC9A7 | c.740T>G p.F247C | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TAF1 | c.1192G>A p.G398R (on ENST00000373790 / NM_138923.4; = p.G419R on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 105/105 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TAFA4 | c.80T>A p.V27E | Missense Mutation (SNP) | VAF 28/336 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.135); called by muse, mutect2
- TOGARAM1 | c.2173A>T p.N725Y | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- ZNF763 | c.136A>G p.K46E (on ENST00000358987 / NM_001367172.2; = p.K49E on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/183 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.039); called by muse, mutect2
- ZNF98 | c.1247G>T p.S416I | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by mutect2, varscan2
- ALG8 | c.90C>T p.P30= | Silent (SNP) | VAF 15/332 reads (5%) | called by muse, mutect2
- CASR | c.2679C>T p.S893= (on ENST00000490131; = p.S970= on NM_000388.4) | Silent (SNP) | VAF 71/525 reads (14%) | catalogued as rs200686461, COSV56133938; called by muse, mutect2, varscan2
- DCLK1 | c.87C>T p.G29= | Silent (SNP) | VAF 113/238 reads (47%) | called by muse, mutect2, varscan2
- FICD | c.1251C>T p.F417= | Silent (SNP) | VAF 133/336 reads (40%) | catalogued as COSV99934125; called by muse, mutect2, varscan2
- GOLGA6C | c.573C>T p.S191= | Silent (SNP) | VAF 246/1132 reads (22%) | called by muse, mutect2, varscan2
- KRT84 | c.1476C>A p.G492= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as rs775878183; called by muse, mutect2, varscan2
- KRTAP20-2 | c.78T>C p.C26= | Silent (SNP) | VAF 249/516 reads (48%) | called by muse, mutect2, varscan2
- MGAM2 | c.1248C>T p.Y416= | Silent (SNP) | VAF 59/215 reads (27%) | catalogued as rs549297711; called by muse, mutect2, varscan2
- MUC16 | c.27513G>A p.S9171= | Silent (SNP) | VAF 163/317 reads (51%) | catalogued as rs372068481; called by muse, mutect2, varscan2
- NKAIN3 | c.327A>G p.E109= | Silent (SNP) | VAF 7/135 reads (5%) | catalogued as COSV100131997; called by muse, mutect2
- PNCK | c.592C>T p.L198= (on ENST00000340888 / NM_001366975.1; = p.L281= on NM_001039582.3) | Silent (SNP) | VAF 73/73 reads (100%) | called by muse, mutect2, varscan2
- SSTR1 | c.57C>A p.G19= | Silent (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- SUPT6H | c.3540G>A p.Q1180= | Silent (SNP) | VAF 10/260 reads (4%) | catalogued as COSV100112207; called by muse, mutect2
- TNFRSF8 | c.1485G>A p.S495= | Silent (SNP) | VAF 136/280 reads (49%) | catalogued as rs777110831; called by muse, mutect2, varscan2
- TTN | c.38121C>T p.H12707= (on ENST00000591111; = p.H5283= on NM_003319.4) | Silent (SNP) | VAF 41/84 reads (49%) | catalogued as rs1060503970; ClinVar: likely benign; called by muse, mutect2, varscan2
- TUT1 | c.1647C>T p.H549= | Silent (SNP) | VAF 9/178 reads (5%) | called by muse, mutect2
- ZNF304 | c.474T>C p.C158= | Silent (SNP) | VAF 99/216 reads (46%) | called by muse, mutect2, varscan2
- CCDC39 | c.2266-545C>A | Intron (SNP) | VAF 47/91 reads (52%) | called by muse, mutect2, varscan2
- CD70 | chr19:6583474 A>T | 3'Flank (SNP) | VAF 19/45 reads (42%) | called by muse, mutect2
- CINP | c.-15A>G | 5'UTR (SNP) | VAF 68/148 reads (46%) | catalogued as rs1476254135; called by muse, mutect2, varscan2
- CLK2P1 | n.787C>T | RNA (SNP) | VAF 211/736 reads (29%) | catalogued as rs1360985658; called by muse, mutect2, varscan2
- CRB1 | c.*1G>A | 3'UTR (SNP) | VAF 109/405 reads (27%) | catalogued as rs776757972; called by muse, mutect2, varscan2
- DENND5B | c.128-4599T>A | Intron (SNP) | VAF 18/40 reads (45%) | called by muse, mutect2, varscan2
- ELMO1 | c.1301-19973C>A | Intron (SNP) | VAF 19/221 reads (9%) | called by muse, mutect2
- GCGR | c.658-22G>A | Intron (SNP) | VAF 176/354 reads (50%) | catalogued as rs774870069; called by muse, mutect2, varscan2
- HMGB1P1 | n.58G>A | RNA (SNP) | VAF 91/231 reads (39%) | called by muse, mutect2, varscan2
- KRT86 | c.-23T>C | 5'UTR (SNP) | VAF 30/599 reads (5%) | called by muse, mutect2
- LRRK2 | c.3496+1758G>T | Intron (SNP) | VAF 81/140 reads (58%) | called by muse, mutect2, varscan2
- MIR9-1 | n.12_14del | RNA (DEL) | VAF 34/95 reads (36%) | called by pindel, varscan2
- PREX1 | c.*25C>T | 3'UTR (SNP) | VAF 39/143 reads (27%) | catalogued as rs769863202; called by muse, mutect2, varscan2
- PXN | c.832-1175C>T | Intron (SNP) | VAF 24/47 reads (51%) | catalogued as rs766168753; called by muse, mutect2, varscan2
- RGS3 | c.467-37T>C | Intron (SNP) | VAF 12/241 reads (5%) | called by muse, mutect2
- RPL37P13 | chr2:62511822 T>A | 5'Flank (SNP) | VAF 87/170 reads (51%) | called by muse, mutect2, varscan2
- SARS2 | c.654-35G>A | Intron (SNP) | VAF 49/360 reads (14%) | called by muse, mutect2, varscan2
